Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YS, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YS-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

ICD-6-3
Fibromyxosarcoma 88113
Site @ Buttock NOS C49.5
8/9/13

....

Clinical Diagnosis & History:

[REDACTED] with buttock malignant fibrous histiocytoma

Specimens Submitted:

1: SP: Radial resection of left buttock mass

DIAGNOSIS:

- 1) SOFT TISSUE AND SKIN, LEFT BUTTOCK MASS; RADICAL RESECTION:
- HIGH GRADE MYXOFIBROSARCOMA DIFFUSELY INFILTRATING SUBCUTANEOUS ADIPOSE TISSUE AND SKELETAL MUSCLE.
- TUMOR MEASURES: 6.5 X 5.8 X 4.8 CM.
- THE TUMOR IS PREDOMINANTLY VIABLE WITH FOCAL AREAS OF NECROSIS.
- SURGICAL MARGINS ARE FREE OF TUMOR. THE TUMOR MEASURES 0.3 CM TO THE NEAREST (MEDIAL) MARGIN. - SKIN WITH SCAR CONSISTENT WITH PRIOR BIOPSY:

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled, "radical resection of left buttock mass, short stitch superior, long stitch lateral", and consists of a single elliptical portion of tissue measuring 16.5 x 15.5 x 10.5 cm. There is an overlying ellipse of skin measuring 17.5 x 3.7 cm. There is a long suture at one tip, which is designated as lateral and a short suture at the superior portion of the specimen. The specimen is inked blue from lateral -- superior -- medial and red from medial -- inferior -- lateral. Upon sectioning, there is a lobulated tan, partially necrotic mass situated within the deep muscle measuring 6.5 x 5.8 x 4.8 cm. The tumor measures 3.5 cm to the skin surface 0.6 cm to the deep soft tissue margin and 1.0 cm to the nearest medial soft tissue margin. Tumor is greater than 3 cm from the

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
additional margin. Tissue is submitted for TPS and photographs are taken.

Summary of sections:

M mass
S skin
LM - lateral margin
SM - superior margin
MM - medial margin
IM -- inferior margin
DM -- deep margin

Summary of Sections:

Part 1: SP: Radial resection of left buttock mass

Block	Sect.	Site	PCs
2		DM	2
1		IM	1
1		LM	1
10		M	10
2		MM	2
1		S	1
1		SM	1

** End of Report **

Criteria	W 7/23/13	Yes	No

Source: NCI Genomic Data Commons file 74762131-ec4f-49e0-9792-15487359e78d (TCGA-DX-A6YS.9C291150-7655-486D-AA2A-FE2CE0966E32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).